Somatic mutation profile of tumor specimen TCGA-RB-AA9M-01A (aliquot TCGA-RB-AA9M-01A-11D-A397-08) from TCGA case TCGA-RB-AA9M, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 43.3 years (15,807 days).
Specimen TCGA-RB-AA9M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 260949e2-c7d6-4327-b58d-85b591ae4287.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RB-AA9M-10A (Blood Derived Normal), aliquot TCGA-RB-AA9M-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1775d3c4-d9be-4145-9a5e-a6a3d0f47a41

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 15/181 reads (8%) | hotspot (GDC flag); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic; called by muse, mutect2
- C10orf90 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 26/561 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767093424, COSV52949033; called by muse, mutect2
- CDKN2A | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131691186, CM024657, CM056560, CM056561, COSV100446060, COSV100446547, COSV58709325; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2
- CNTN4 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs977295576, COSV68565725; called by muse, mutect2
- FYB1 | c.1871T>A p.I624N | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100685467; called by muse, mutect2
- GRIK2 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 25/357 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs867348031, COSV100026379; called by muse, mutect2
- KIAA0895 | c.962G>A p.R321H (on ENST00000297063 / NM_001100425.2; = p.R270H on NM_015314.3) | Missense Mutation (SNP) | VAF 27/578 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260673515, COSV99766865; called by muse, mutect2
- MAP2 | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 25/464 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV52299972; called by muse, mutect2
- MUC17 | c.2840C>G p.T947S | Missense Mutation (SNP) | VAF 85/1900 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100073432; called by muse, mutect2
- PRB1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 70/1278 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1167945774, COSV53702862; called by muse, mutect2
- PRKACB | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 38/578 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100853939; called by muse, mutect2
- SDCBP | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 36/646 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1430532079, COSV99486352; called by muse, mutect2
- SLC45A4 | c.874G>A p.E292K (on ENST00000517878 / NM_001286646.2; = p.E241K on NM_001080431.2) | Missense Mutation (SNP) | VAF 68/998 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs765022689, COSV99198395; called by muse, mutect2
- ZBTB47 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99234233; called by muse, mutect2
- ZNF70 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs758961016, COSV59532582; called by muse, mutect2
- ZNF831 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV64042138; called by muse, mutect2
- CMYA5 | c.7806C>T p.L2602= | Silent (SNP) | VAF 19/207 reads (9%) | catalogued as rs1386825846, COSV101484070; called by muse, mutect2
- FCN1 | c.681C>T p.D227= | Silent (SNP) | VAF 77/1303 reads (6%) | catalogued as rs145090957; called by muse, mutect2
- PCNT | c.9051C>T p.H3017= | Silent (SNP) | VAF 31/530 reads (6%) | catalogued as COSV100855551; called by muse, mutect2
- RNF17 | c.3838C>T p.L1280= | Silent (SNP) | VAF 54/1194 reads (5%) | catalogued as COSV99693308; called by muse, mutect2
- SEMA6D | c.1023A>G p.K341= | Silent (SNP) | VAF 24/450 reads (5%) | catalogued as COSV100317000; called by muse, mutect2
- TTN | c.75858C>T p.N25286= (on ENST00000591111; = p.N17862= on NM_003319.4) | Silent (SNP) | VAF 48/832 reads (6%) | catalogued as rs747688310, COSV100614547; called by muse, mutect2
- ZNF773 | c.510G>A p.T170= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as rs149516480, COSV99989467; called by muse, mutect2, varscan2
